Somatic mutation profile of tumor specimen TCGA-CD-5802-01A (aliquot TCGA-CD-5802-01A-11D-1600-08) from TCGA case TCGA-CD-5802, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 58.4 years (21,331 days).
Specimen TCGA-CD-5802-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 068355a9-69f0-41ae-ba31-8f3d47d56dfd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-5802-10A (Blood Derived Normal), aliquot TCGA-CD-5802-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b7cfc97-a46b-455c-877a-45eaa9205f0d

The open-access MAF lists 57 somatic variants for this specimen: 41 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 14, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 1, Splice Site 1, In Frame Del 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGAP2 | c.296C>G p.A99G | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs1432651459, COSV54066033; called by muse, mutect2, varscan2
- ASB5 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | catalogued as COSV56668461, COSV56670474; called by muse, mutect2
- BPNT1 | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs564542643, COSV59039886; called by muse, mutect2, varscan2
- C4orf50 | c.427G>A p.V143I (on ENST00000324058; = p.V1375I on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs750915133, COSV100135761, COSV60688547; called by muse, mutect2, varscan2
- C9orf131 | c.3179A>G p.Q1060R | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as COSV56611041; called by muse, mutect2, varscan2
- COL24A1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.061); catalogued as rs1320375371, COSV65305903; called by muse, mutect2
- DGKA | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 76/952 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV59385989; called by muse, mutect2
- EMILIN3 | c.677T>C p.F226S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV60036138; called by muse, mutect2, varscan2
- F12 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.519); catalogued as COSV53691320; called by muse, mutect2, varscan2
- FANCM | c.4698G>A p.M1566I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV57500929; called by muse, mutect2, varscan2
- FIBP | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs766679393, COSV57027948, COSV57029414; called by muse, mutect2, varscan2
- FOXL2NB | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.389); catalogued as rs757845000, COSV57727003; called by muse, mutect2, varscan2
- GALNT8 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); catalogued as rs886503126, COSV52897273; called by muse, mutect2, varscan2
- GHSR | c.535T>A p.F179I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV53839193; called by muse, mutect2, varscan2
- GPR39 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV61423325; called by muse, mutect2, varscan2
- GSG1 | c.479G>A p.R160K (on ENST00000651961 / NM_001080555.4; = p.R124K on NM_031289.5) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.832); catalogued as COSV60971397; called by muse, mutect2, varscan2
- KCNF1 | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54463336; called by muse, mutect2, varscan2
- KCNH8 | c.570+1G>A p.X190_splice | Splice Site (SNP) | VAF 27/133 reads (20%) | catalogued as rs755303397, COSV60463215; called by muse, mutect2, varscan2
- LRRC8B | c.2392del p.T798Rfs*3 | Frame Shift Del (DEL) | VAF 46/222 reads (21%) | catalogued as COSV58376760; called by mutect2, pindel, varscan2
- MS4A14 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.346); catalogued as COSV55734768, COSV99038259; called by muse, mutect2, varscan2
- MYCBP2 | c.9336G>A p.M3112I (on ENST00000357337; = p.M3150I on NM_015057.5) | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1261027973, COSV62018187; called by muse, mutect2, varscan2
- NEXN | c.965G>C p.R322T | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV57357195; called by muse, mutect2, varscan2
- PRR5L | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV100287068, COSV61121294; called by muse, mutect2
- RFC4 | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV56216896; called by muse, mutect2
- RHBDL3 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs776334303, COSV52186052, COSV52188520; called by muse, mutect2, varscan2
- RING1 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1204881780, COSV63002527; called by muse, mutect2, varscan2
- RNF216 | c.372G>T p.L124F (on ENST00000425013 / NM_207116.3; = p.L181F on NM_207111.4) | Missense Mutation (SNP) | VAF 108/581 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV66290408; called by muse, mutect2, varscan2
- SMOC2 | c.173G>T p.R58M | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62437532; called by muse, mutect2, varscan2
- SULF1 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs758690728, COSV52674097; called by muse, mutect2, varscan2
- SUPT5H | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63239286; called by muse, mutect2, varscan2
- TBCCD1 | c.1241T>C p.V414A | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV58662111; called by muse, mutect2, varscan2
- TNS1 | c.3310C>T p.R1104W | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs373946458, COSV50702187; called by muse, mutect2
- USP54 | c.4879C>T p.R1627* | Nonsense Mutation (SNP) | VAF 33/135 reads (24%) | catalogued as rs779266508, COSV60442351; called by muse, mutect2, varscan2
- WNK1 | c.5645C>T p.S1882F (on ENST00000315939 / NM_018979.4; = p.S1634F on NM_014823.3) | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV60032644; called by muse, mutect2, varscan2
- ZFYVE26 | c.3826C>T p.P1276S | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV61328174; called by muse, mutect2, varscan2
- ABCA9 | c.3207_3217del p.Q1070Gfs*20 | Frame Shift Del (DEL) | VAF 36/259 reads (14%) | called by mutect2, pindel, varscan2
- LTBP4 | c.3123del p.T1042Rfs*51 (on ENST00000308370 / NM_001042544.1; = p.T1005Rfs*51 on NM_003573.2) | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | called by mutect2, pindel, varscan2
- NCBP3 | c.1768C>T p.Q590* | Nonsense Mutation (SNP) | VAF 37/227 reads (16%) | called by muse, mutect2, varscan2
- SREBF2 | c.122_123del p.E41Vfs*3 | Frame Shift Del (DEL) | VAF 47/310 reads (15%) | called by pindel, varscan2
- TBCCD1 | c.1397_1399del p.F466del | In Frame Del (DEL) | VAF 46/259 reads (18%) | called by mutect2, pindel, varscan2
- ZC3H15 | c.716_717dup p.R240Sfs*5 | Frame Shift Ins (INS) | VAF 22/124 reads (18%) | called by mutect2, varscan2
- CKM | c.526C>T p.L176= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV55533029; called by muse, mutect2, varscan2
- CREB5 | c.1011C>T p.T337= (on ENST00000357727 / NM_182898.4; = p.T330= on NM_004904.3) | Silent (SNP) | VAF 44/283 reads (16%) | catalogued as rs369220982; called by muse, mutect2, varscan2
- DGKA | c.1014C>T p.V338= | Silent (SNP) | VAF 52/436 reads (12%) | catalogued as COSV59385979; called by muse, mutect2, varscan2
- EFTUD2 | c.1473C>T p.H491= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as rs149288120; called by muse, mutect2, varscan2
- ESCO2 | c.1758C>G p.T586= | Silent (SNP) | VAF 43/249 reads (17%) | catalogued as COSV59414467; called by muse, mutect2, varscan2
- FREM1 | c.5601C>T p.S1867= | Silent (SNP) | VAF 81/427 reads (19%) | catalogued as COSV66523112; called by muse, mutect2, varscan2
- GDF7 | c.1227G>A p.A409= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs1182817522, COSV55347665; called by muse, mutect2
- IDH3G | c.837C>T p.I279= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs141309746, COSV54207470; called by muse, mutect2, varscan2
- MAPKBP1 | c.3768C>A p.A1256= (on ENST00000456763 / NM_001128608.2; = p.A1250= on NM_014994.3) | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV52961230; called by muse, mutect2, varscan2
- NCBP3 | c.1767G>A p.E589= | Silent (SNP) | VAF 36/222 reads (16%) | catalogued as COSV99339671; called by muse, mutect2, varscan2
- PPP4R1 | c.60G>A p.V20= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as rs746130013, COSV53281699, COSV99553637; called by muse, mutect2, varscan2
- SUOX | c.579C>T p.P193= | Silent (SNP) | VAF 18/434 reads (4%) | catalogued as COSV56268227; called by muse, mutect2
- TCF23 | c.426G>A p.P142= | Silent (SNP) | VAF 67/381 reads (18%) | catalogued as rs1044613600, COSV56077846, COSV56078859; called by muse, mutect2, varscan2
- ZFP57 | c.132C>T p.V44= | Silent (SNP) | VAF 68/260 reads (26%) | catalogued as COSV65306088; called by muse, mutect2, varscan2
- TTI2 | chr8:33513512 C>T | 5'Flank (SNP) | VAF 52/241 reads (22%) | catalogued as rs185083029, COSV100659807; called by muse, mutect2, varscan2
- ZNF419 | c.298+48C>T | Intron (SNP) | VAF 27/156 reads (17%) | catalogued as COSV99692556; called by muse, mutect2, varscan2
